Gene-level copy-number profile of tumor specimen HCM-CSHL-0182-C25-01A from HCMI case HCM-CSHL-0182-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 74.6 years (27,264 days).
Specimen HCM-CSHL-0182-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 26a3e518-1028-4698-a414-1a6cfe109e05.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0182-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/8c15dc09-c861-4298-891b-e78deb48bd77

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 7,129; copy number 2: 37,892; copy number 3: 10,018; copy number 4: 2,962; copy number 5: 26; copy number 6: 87; copy number 7: 8; copy number 8: 144; copy number 10: 5; copy number 12: 88; copy number 15: 21; copy number 16: 3; copy number 17: 2; copy number 18: 6.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr4:69,346,609–69,358,177, 1 gene (within-gene range 0–1): AC114786.2.
- chr9:42,921,443–43,045,120, 6 genes: CR848007.2, SNX18P5, CYP4F60P, CR848007.1, CNN2P4, AL591441.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 384 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:105,433,994–107,965,180, 17 genes, copy number 5–7 (within-gene range 4–7): CDK4P1, LINC01676, SEPTIN2P1, AL512844.2, AL512844.1, LINC01677, AL355306.2, AL355306.1, AL499605.1, AL596327.1, MTATP6P14, MTCO1P14, LINC01661, PRMT6, NTNG1, NDUFA4P1, VAV3.
- chr6:41,494,853–52,087,613, 205 genes, copy number 6–18 (within-gene range 3–18) (broad region; genes not listed).
- chr10:79,661,394–79,826,594, 1 gene, copy number 6 (within-gene range 4–6): NUTM2B-AS1.
- chr10:79,703,227–79,714,681, 1 gene, copy number 6: NUTM2B.
- chr18:60,628,963–61,758,464, 11 genes, copy number 5 (within-gene range 3–5): AC113137.1, CTBP2P3, HMGN1P31, CDH20, RNU6-116P, RPL30P14, AC090409.2, AC090409.1, AC105094.2, AC105094.1, LINC01544.
- chr20:20,389,530–26,251,546, 149 genes, copy number 8–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,778. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
